CCDI case PBCJIC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/dce40bfe-a4e9-40ac-a5e7-e51d544c3860

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: External ear; Age at diagnosis: 7.2 years (2,624 days).

Biospecimens (3 samples)
- Sample 0DTGCZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTGDA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTGDF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
